Somatic mutation profile of tumor specimen 0DI3NH from CCDI case PBBVCP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 2.0 years (734 days).
Specimen 0DI3NH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 398e630c-4567-40ec-b596-d013b2e3d04c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI3JF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acd22f46-53af-408a-ba73-9b4c744af17a

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK5 | c.2580G>A p.M860I | Missense Mutation (SNP) | VAF 81/652 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV52398901; called by muse, mutect2, varscan2
- NLRP5 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 74/475 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as rs370513314; called by muse, mutect2, varscan2
- PRR14L | c.2588C>T p.T863M | Missense Mutation (SNP) | VAF 84/864 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs371047881; called by muse, mutect2
- OR4C46 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 262/681 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- MAP1LC3C | c.333G>A p.E111= | Silent (SNP) | VAF 31/843 reads (4%) | catalogued as COSV61803930; called by muse, mutect2
- PICK1 | c.835-38G>A | Intron (SNP) | VAF 97/253 reads (38%) | catalogued as rs773979368; called by muse, mutect2, varscan2
- RGPD2 | c.-44T>G | 5'UTR (SNP) | VAF 10/112 reads (9%) | catalogued as rs748293018, COSV59529929; called by muse, mutect2
